Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3LY, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3LY-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Physician: [REDACTED]

CC: [REDACTED]

Patient Address: [REDACTED]

Date of Receipt: [REDACTED]

Date of Report: [REDACTED]

....

Clinical Diagnosis & History:

Specimens Submitted:

1: Right retroperitoneal lymph node dissection, right kidney and right adrenal gland

DIAGNOSIS:

1. Soft tissue, right retroperitoneum, right kidney and right adrenal gland, mass, resection:

- High grade Spindle cell sarcoma compatible with Dedifferentiated liposarcoma. (see Note)
- The tumor measures 18.2 cm in greatest dimension.
- The dedifferentiated component includes a high grade spindle cell sarcoma.
- Tumor does not involve the kidney or adrenal gland.
- Tumor extends close to (less than 0.1 cm) the resection margin.

Note: The retroperitoneal mass shows a high grade spindle cell sarcoma composed of spindle cells in a predominantly palisading pattern (schwannian). Focal areas show spindle cells in a loose, partially myxoid, background with scattered large atypical cells. Mitoses, upto 7 per 10 hpf, are identified. The surrounding peri-renal adipose tissue shows mild atypia, but morphologic features are insufficient for a definitive diagnosis of a well differentiated liposarcoma. Immunohistochemical stains show that the tumor cells are positive for CD34, CDK4 (focal) and MDM2 (focal weak) and negative for S100, SMA, Desmin and CD117. A MIB 1(KI67) stains shows a high proliferation rate of 15-20%. Based on the morphology, this represents a high grade spindle cell sarcoma compatible with a dedifferentiated liposarcoma. The focal nature of the CDK4 and MDM2 staining is uncharacteristic of this entity. FISH studies are being performed to confirm this diagnostic impression.

This case was also reviewed by Dr. [REDACTED]

[REDACTED], who agrees with the above interpretation.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED

** Continued on next page **

1CD-0-3

Dedifferentiated liposarcoma 8858/3

Site: retroperitoneum C48.0

lw
12/23/11

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Accession #. [REDACTED]

Date of Report: [REDACTED]

Page 2 of 3

THIS REPORT.

Na-

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	
	Unst_Recut	

Gross Description:

1). Received fresh and labeled "right retroperitoneal lymph node dissection, right kidney, right adrenal gland" is a 1355 gm resection of adrenal gland (6.0 x 2.9 x 0.7cm), kidney (10.1 x 6.5 x 2.5 cm) with attached ureter (12cm in length by 0.3cm in diameter), renal vein (0.4cm in length by 0.3cm in diameter) and a soft tissue mass (18.2 x 11 x 9.2cm). The mass is grossly surrounding the kidney and ureter but not invading them, and has some areas of hemorrhage (20%) and necrosis (10%). Scant mucinous cystic areas are identified as well. There is an area which is well defined and is white and firm, measuring 3cm in greatest dimension. The mass is contained within the fat surrounding the kidney, but comes within 0.1 cm to the surface of the specimen. A portion of fat surrounding the kidney, measuring 17 x 10 x 6 cm, is yellow tan and lobulated. The adrenal gland and kidney are grossly unremarkable. Pictures taken and tissue submitted for

Summary of sections

VM - vascular resection margin
U - ureter resection margin
Ad - adrenal gland
K - kidney
MH - mass hemorrhagic areas
MN - mass necrotic areas
MC - mass cystic areas
M - mass
MW - mass white firm area
A - adipose tissue around kidney

Summary of Sections:

Part 1: Right retroperitoneal lymph node dissection, right kidney and right adrenal gland

Block	Sect.	Site	PCs
10		A	10
1		Ad	1

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Accession #: [REDACTED]

Date of Report: [REDACTED]

Page 3 of 3

2	K	2
9	M	9
6	MC	6
2	MH	2
3	MN	3
4	MW	4
1	U	1
1	VM	1

** End of Report **

Prior Malignancy/Histology		

Source: NCI Genomic Data Commons file b5c5de95-82d9-4d82-8e02-c81bfa2d95a3 (TCGA-DX-A3LY.4BD1FBCC-6C96-47D2-862A-843040E37C02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).